Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2P1, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2P1-06A (Metastatic).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: M

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering

MD:

Copy To:

Specimen(s) Received

1. Lymph-Node: left, level 6
2. Thyroid: total, bilateral levels 6,7 and right levels 3&4
3. Soft Tissue: rt level 3 node
4. Neck: left

Casualty (circle):		
Path Reviewed:		

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 8/31/11

Diagnosis

1. No pathological diagnosis: Lymph node, 1 (left neck level VI) excisional biopsy
2. Widely invasive papillary carcinoma, Warthin-like variant with focal follicular growth, 3.1 cm, left; and severe chronic lymphocytic thyroiditis and mild nodular hyperplasia: Thyroid
Metastatic papillary thyroid carcinoma with focal extranodal extension: Lymph nodes, 3 of 3 (bilateral neck level VI and VII)
Metastatic papillary thyroid carcinoma: Lymph nodes, 4 of 6 (right neck level III and IV)
Invasive papillary thyroid carcinoma: Parathyroid gland, left perithyroidal
No pathological diagnosis: Parathyroid gland, right perithyroidal
No pathological diagnosis: Thymus
- Total thyroidectomy with (bilateral level VI and VII, and right level III and IV neck) dissection specimen
3. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 1 (right level III) excisional biopsy
4. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 19 (level IIA)
Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 3 (level IIB)
Metastatic papillary thyroid carcinoma with focal extranodal extension: Lymph node, 1 of 15 (level III)
Metastatic papillary thyroid carcinoma with focal extranodal extension: Lymph nodes, 2 of 6 (level IV)
- (Left neck level IIA, IIB, III and IV) dissection specimen

Synoptic Data

[page 2 of 4]
Procedure:	Total thyroidectomy with bilateral neck dissection
Received:	In formalin
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.1 cm
	2.2 cm
	1.2 cm
	Left lobe:
	3.2 cm
	2.2 cm
	0.9 cm
	Isthmus +/- pyramidal lobe:
	2.5 cm
	1.8 cm
	0.4 cm
	Central compartment:
	6.0 cm
	6.5 cm
	1.0 cm
Specimen Weight:	35.0 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 3.1 cm
	Additional dimension: 1.5 cm
	Additional dimension: 0.9 cm
Histologic Type:	Papillary carcinoma, Warthin-like variant
	Papillary carcinoma, other variant: with focal follicular growth
	Classical (papillary) architecture
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 0.1 mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Present
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
	Number of regional lymph nodes examined: 54
	Number of regional lymph nodes involved: 15
	Lymph Node, Extranodal Extension Present
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis, other: chronic lymphocytic thyroiditis
	Parathyroid gland(s), within normal limits
	Parathyroid gland(s), other: invasive papillary carcinoma (left), normal limits (right)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 3 of 4]
verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "Left level VI" contains one piece of tan tissue measuring 0.9 x 0.5 x 0.4 cm received in 10% buffered formalin.

1A submitted in toto

2. The specimen labeled with the patient's name and as "Left Thyroid, Bilateral Level 6 and 7 and Right Level 3 and 4" consists of a thyroid gland and attached neck dissection received attached to a green towel and is oriented by the surgeon weighing 35.0 g. The right thyroid lobe measures 4.1 cm SI x 2.2 cm ML x 1.2 cm AP, the left thyroid lobe measures 3.2 cm SI x 2.2 cm ML x 0.9 cm AP and the isthmus measures 2.5 cm SI x 1.8 cm ML x 0.4 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The neck dissection measures 6.0 cm SI x 6.5 cm ML x 1.0 cm AP. The left lobe contains ill-delineated nodule that measures 3.1 cm SI x 1.5 cm ML x 0.9 cm AP. The isthmus contains a well delineated nodule that measures 0.4 cm SI x 0.3 cm ML x 0.4 cm AP. The remainder of the thyroid tissue is unremarkable. Left level 6-7 demonstrates a tumor that measures 2.5 cm SI x 1.6 cm ML x 0.9 cm AP. The tumor is firm and yellow tan. The right level 3-4 demonstrates a tumor mass that measures 2.1 cm SI x and 1.3 cm ML x 0.8 cm AP. Additional lymph nodes that range from 0.2 to 2.0 cm are identified. Tissue is stored frozen. Representative sections are submitted.

2A-F right lobe, superior to inferior submitted in toto

2G-H isthmus submitted in toto

2I-M left lobe, superior to inferior submitted in toto

Bilateral Level 6-7

2N-O tumor

2P one lymph node

2Q one lymph node bisected

Right Level 3-4

2R-S tumor

2T-U multiple lymph nodes in each block

2V one lymph node bisected

3. The specimen labeled with the patient's name and as "Right Level 3 Node", contains one piece of yellow-tan tissue measuring 1.3 x 0.9 x 0.4 cm received in 10% buffered formalin.

3A submitted in toto

4. The specimen labeled with the patient's name and as "Left Neck". It consists of a left neck dissection received attached to a green towel and oriented by the surgeon with overall dimensions of 12.5 x 8.6 x 1.7 cm. The internal jugular vein is not identified. The sternocleidomastoid is unremarkable and measures 3.2 x 1.7 x 1.1 cm. Multiple lymph nodes are

[page 4 of 4]
identified the largest measuring 2.8 x 1.3 x 1.6 and 2.3 x 1.9 x 1.6 cm which are identified in levels 3 and 4. Tissue is stored frozen. Representative sections are submitted.

Level 2A

- 4A-C** multiple lymph nodes in each block
- 4D-F** one lymph node bisected in each block
- 4G-H** one lymph node serially sectioned

Level 2B

- 4I** one lymph node bisected
- 4J-K** one lymph node trisected
- 4L-M** one lymph node trisected

Level 3

- 4N-P** multiple lymph nodes in each block
- 4Q** one lymph node bisected
- 4R-U** one lymph node serially sectioned

Level 4

- 4V** multiple lymph nodes
- 4W** one lymph node bisected
- 4X-AB** one lymph node serially sectioned
-

Source: NCI Genomic Data Commons file 1611daed-3bd5-44e5-9ba0-e04377a19f2c (TCGA-EM-A2P1.793EF89D-75B5-43C3-B567-766836B52676.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).